Somatic mutation profile of tumor specimen TCGA-21-1078-01A (aliquot TCGA-21-1078-01A-01W-0782-08) from TCGA case TCGA-21-1078, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.0 years (28,125 days).
Specimen TCGA-21-1078-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43fcb031-efa5-4d94-bc25-59daaca75ec7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1078-11A (Solid Tissue Normal), aliquot TCGA-21-1078-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e26181a6-f4e9-4e8c-9e1e-8cccde248e32

The open-access MAF lists 78 somatic variants for this specimen: 63 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 13, Nonsense Mutation 4, Frame Shift Ins 2, In Frame Del 2, Frame Shift Del 2, Splice Region 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 262/610 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALX4 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368050443; called by muse, mutect2, varscan2
- ANKLE2 | c.1214A>C p.N405T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61709411; called by muse, mutect2, varscan2
- ANKRD20A2P | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0.301); catalogued as COSV66464271; called by muse, mutect2
- ANKRD50 | c.1428A>G p.I476M | Missense Mutation (SNP) | VAF 102/235 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV72385534; called by muse, mutect2, varscan2
- ARHGAP22 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV50942328; called by muse, mutect2, varscan2
- ATP13A5 | c.1834C>T p.Q612* | Nonsense Mutation (SNP) | VAF 105/202 reads (52%) | catalogued as rs139981143; called by muse, mutect2, varscan2
- BAP1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV56230024, COSV56234275; called by muse, mutect2, varscan2
- BBS10 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV53882265; called by muse, mutect2, varscan2
- BRCA2 | c.8458G>A p.V2820I | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV66453515; called by muse, mutect2, varscan2
- CCDC60 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 175/445 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778425978, COSV59543287; called by muse, mutect2, varscan2
- CCL16 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 308/727 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as rs1234722629; called by muse, mutect2, varscan2
- CD276 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs1475271856, COSV59203649; called by muse, mutect2, varscan2
- COL11A1 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.932); catalogued as COSV62183345; called by muse, mutect2, varscan2
- CSGALNACT1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV59977384; called by muse, mutect2, varscan2
- CSTF2T | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV58656433; called by muse, mutect2, varscan2
- DHX30 | c.895G>C p.E299Q (on ENST00000445061 / NM_138615.3; = p.E260Q on NM_014966.3) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.368); catalogued as COSV62394504; called by muse, mutect2, varscan2
- DNAH6 | c.1969C>T p.H657Y | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.326); catalogued as rs1480687487, COSV52860260; called by muse, mutect2, varscan2
- DOP1A | c.6235C>G p.H2079D | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52710173; called by muse, varscan2
- DRP2 | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 83/97 reads (86%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV65810309; called by muse, mutect2, varscan2
- GON4L | c.1687G>T p.E563* | Nonsense Mutation (SNP) | VAF 103/219 reads (47%) | catalogued as COSV55193295, COSV55195839; called by muse, mutect2, varscan2
- GUCY1A2 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as COSV56486189; called by muse, mutect2, varscan2
- HLTF | c.1300G>T p.V434F | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.17); catalogued as COSV59500613; called by muse, mutect2, varscan2
- HUWE1 | c.8485C>G p.P2829A | Missense Mutation (SNP) | VAF 52/56 reads (93%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53340567, COSV53344938; called by muse, mutect2
- KCNH3 | c.2947C>T p.Q983* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV57790742; called by muse, mutect2, varscan2
- KL | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.71); PolyPhen benign (0.134); catalogued as COSV66308744; called by muse, mutect2, varscan2
- KRAS | c.353G>C p.C118S | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV55711743; called by muse, mutect2, varscan2
- MAP4 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 298/673 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV64239536; called by muse, mutect2, varscan2
- MCM3AP | c.4399G>A p.E1467K | Missense Mutation (SNP) | VAF 200/514 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV52439571; called by muse, mutect2, varscan2
- MOXD1 | c.579C>T p.D193= | Splice Region (SNP) | VAF 76/195 reads (39%) | catalogued as rs373772503; called by muse, mutect2, varscan2
- MUC16 | c.18349G>T p.D6117Y | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV67453016, COSV67464944; called by muse, mutect2, varscan2
- N4BP2 | c.3032T>C p.V1011A | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs760315776, COSV54701787; called by muse, mutect2, varscan2
- NCR2 | c.231G>C p.W77C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV66100564; called by muse, mutect2, varscan2
- OR10A3 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 126/274 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444625700, COSV100660265, COSV62459476; called by muse, mutect2, varscan2
- OR2M2 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 381/834 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs868746148, COSV62897895, COSV62898040; called by muse, mutect2, varscan2
- PIGL | c.142G>C p.A48P | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51974175; called by muse, mutect2, varscan2
- PLIN3 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs758721515, COSV55735235; called by muse, mutect2, varscan2
- PPFIA1 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.247); catalogued as COSV54134408; called by muse, mutect2, varscan2
- PPFIA1 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 107/253 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54134419; called by muse, mutect2, varscan2
- PREX2 | c.1129A>G p.M377V | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.325); catalogued as rs1348317702, COSV55768867; called by muse, mutect2, varscan2
- RAD51D | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 122/248 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60004036, COSV60004730; called by muse, mutect2, varscan2
- RGS3 | c.3096G>C p.K1032N (on ENST00000350696 / NM_001282923.2; = p.K751N on NM_130795.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV59516250; called by muse, mutect2, varscan2
- SHBG | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52646765; called by muse, mutect2, varscan2
- SI | c.1516A>G p.M506V | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs1302522597, COSV52277871; called by muse, mutect2, varscan2
- SLC33A1 | c.914T>C p.I305T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs1200785764, COSV63947105; called by muse, mutect2, varscan2
- SMG7 | c.2002A>T p.T668S | Missense Mutation (SNP) | VAF 117/225 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as COSV61631217; called by muse, mutect2, varscan2
- SPTA1 | c.5577G>A p.M1859I | Missense Mutation (SNP) | VAF 28/297 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV63752842; called by muse, mutect2
- STYK1 | c.1232G>C p.R411T | Missense Mutation (SNP) | VAF 179/438 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV50013191, COSV50014094; called by muse, mutect2, varscan2
- THBS2 | c.1599C>A p.C533* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV64677830; called by muse, mutect2, varscan2
- TNFRSF1B | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66164240, COSV66164820; called by muse, mutect2, varscan2
- TSNAXIP1 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54649744; called by muse, mutect2, varscan2
- YLPM1 | c.6091G>C p.E2031Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV53111637; called by muse, mutect2, varscan2
- ZNF839 | c.572C>T p.S191F (on ENST00000558850 / NM_001267827.1; = p.S307F on NM_018335.5) | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.612); catalogued as rs1234555970, COSV51757326; called by muse, mutect2, varscan2
- ZSWIM5 | c.3409G>C p.E1137Q | Missense Mutation (SNP) | VAF 145/315 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs751715498, COSV55800199; called by muse, mutect2, varscan2
- ARID1A | c.1345_1346dup p.Q449Hfs*171 | Frame Shift Ins (INS) | VAF 25/83 reads (30%) | called by mutect2, pindel, varscan2
- BAP1 | c.470_490del p.N157_R163del | In Frame Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- CREBBP | c.4344del p.V1449Ffs*10 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by pindel, varscan2
- KIF16B | c.2580_2581del p.L861Rfs*6 | Frame Shift Del (DEL) | VAF 204/250 reads (82%) | called by mutect2, varscan2
- KMT2C | c.7478_7479insA p.S2494Efs*31 | Frame Shift Ins (INS) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- SLC29A3 | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- SMCHD1 | c.732_734del p.F245del | In Frame Del (DEL) | VAF 69/182 reads (38%) | called by pindel, varscan2
- ZSCAN18 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- AHNAK2 | c.12735G>C p.L4245= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV60909766; called by muse, mutect2, varscan2
- AHNAK2 | c.12597G>A p.V4199= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV60915057; called by muse, varscan2
- CUL9 | c.6798C>G p.L2266= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as COSV52728421, COSV52728568; called by muse, mutect2, varscan2
- ECPAS | c.2043G>A p.L681= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52196882; called by muse, mutect2, varscan2
- FAM90A1 | c.288G>A p.L96= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as COSV56711995; called by muse, mutect2, varscan2
- KIAA0753 | c.2874C>T p.F958= | Silent (SNP) | VAF 295/685 reads (43%) | catalogued as COSV63817363; called by muse, varscan2
- KLHDC9 | c.780G>C p.R260= | Silent (SNP) | VAF 189/412 reads (46%) | catalogued as COSV63509638; called by muse, mutect2, varscan2
- MDH2 | c.450C>A p.I150= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV59884312; called by muse, mutect2, varscan2
- PARP4 | c.1884C>T p.I628= | Silent (SNP) | VAF 83/194 reads (43%) | catalogued as COSV67961719; called by muse, mutect2, varscan2
- RAF1 | c.258C>G p.L86= | Silent (SNP) | VAF 153/283 reads (54%) | catalogued as COSV52578223; called by muse, mutect2, varscan2
- SRGAP2 | c.2013C>T p.I671= (on ENST00000624873 / NM_001170637.4; = p.I672= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 243/556 reads (44%) | catalogued as COSV55337318; called by muse, mutect2, varscan2
- WNK1 | c.7092C>T p.I2364= (on ENST00000315939 / NM_018979.4; = p.I2116= on NM_014823.3) | Silent (SNP) | VAF 74/182 reads (41%) | catalogued as COSV57272912; called by muse, mutect2, varscan2
- ZNF236 | c.2313C>G p.L771= | Silent (SNP) | VAF 154/500 reads (31%) | catalogued as rs1363014259, COSV53488033; called by muse, mutect2, varscan2
- EP400 | c.5755-708G>T | Intron (SNP) | VAF 34/441 reads (8%) | catalogued as COSV57776022, COSV57783965; called by muse, mutect2
- L1CAM | chrX:153887036 G>A | 5'Flank (SNP) | VAF 10/12 reads (83%) | called by muse, mutect2, varscan2
